Gene-level copy-number profile of tumor specimen C3N-00305-02 from CPTAC case C3N-00305, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 60.1 years (21,957 days).
Specimen C3N-00305-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b8fcf922-38ac-42bd-824d-9e65c197a3f5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00305-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/3f3484be-3781-464a-992d-b090df023da2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,351; copy number 1: 3; copy number 2: 53,492; copy number 3: 34; copy number 4: 3,520.

Homozygous deletions (total copy number 0; autosomes only): 1,351 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–89,482,134, 1,341 genes (broad region; genes not listed).
- chr9:12,134–73,865, 5 genes (within-gene range 0–2): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C.
- chr10:47,995,322–48,119,455, 5 genes: FAM25C, AGAP12P, RNA5SP315, BMS1P7, PTPN20CP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
